Somatic mutation profile of tumor specimen MMRF_2149_1_BM_CD138pos (aliquot MMRF_2149_1_BM_CD138pos_T1_KHS5U_L11066) from MMRF case MMRF_2149, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,061 days).
Specimen MMRF_2149_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e45bf274-85bd-47ee-8593-bb5147d8873b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2149_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2149_1_PB_Whole_C3_KHS5U_L08781; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/237238ef-55ad-447a-99cd-e57c91ef8bc7

The open-access MAF lists 91 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 26, Intron 17, Silent 9, 3'Flank 3, Splice Site 2, RNA 2, 5'UTR 2, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 88/200 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C2CD6 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.496); catalogued as rs772309336, COSV99632711; called by muse, mutect2, varscan2
- DSCAML1 | c.388G>A p.V130M (on ENST00000321322; = p.V70M on NM_020693.4) | Missense Mutation (SNP) | VAF 90/141 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393957887, COSV58382031; called by muse, mutect2, varscan2
- H1-2 | c.228C>G p.N76K | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs778226952; called by muse, mutect2, varscan2
- H1-4 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99175189; called by muse, mutect2, varscan2
- IGHJ5 | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 16/16 reads (100%) | catalogued as rs563513909; called by muse, varscan2
- IGHV3-21 | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 75/77 reads (97%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.076); catalogued as rs782422955; called by muse, varscan2
- IGLV3-21 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs369416480; called by muse, varscan2
- IGLV3-25 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769248639; called by muse, varscan2
- OSBPL7 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs201720672; called by muse, mutect2, varscan2
- PLCB1 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62063857; called by muse, mutect2
- SEPTIN12 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs369327426; called by muse, mutect2, varscan2
- TENT5C | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65616734; called by muse, mutect2, varscan2
- TXNDC16 | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1310074667, COSV55984621; called by muse, mutect2, varscan2
- CAPN1 | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- CYFIP1 | c.2629A>G p.R877G | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FREM1 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GGNBP2 | c.1526_1527del p.K509Rfs*3 | Frame Shift Del (DEL) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- IFT52 | c.-6-2A>T | Splice Site (SNP) | VAF 64/251 reads (25%) | called by muse, mutect2, varscan2
- KRT31 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2
- LBR | c.911T>A p.L304Q | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYADM | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 300/457 reads (66%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- NEB | c.718-1G>A p.X240_splice | Splice Site (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- NUDT21 | c.382A>T p.I128L | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PRKD2 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM25 | c.2202G>T p.K734N | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RET | c.2074G>C p.A692P | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- SCN1B | c.411C>G p.S137R | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SF3B1 | c.1239+4G>A | Splice Region (SNP) | VAF 55/239 reads (23%) | called by muse, mutect2, varscan2
- TSPAN19 | c.344A>C p.Q115P | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT16 | c.89A>C p.N30T | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACSS3 | c.702C>T p.Y234= | Silent (SNP) | VAF 76/170 reads (45%) | catalogued as rs569413055, COSV54100213; called by muse, mutect2, varscan2
- CHD8 | c.6948T>C p.P2316= (on ENST00000646647 / NM_001170629.2; = p.P2037= on NM_020920.4) | Silent (SNP) | VAF 112/226 reads (50%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.315C>T p.Y105= | Silent (SNP) | VAF 19/20 reads (95%) | catalogued as rs184596906; called by muse, varscan2
- PTCHD1 | c.1980A>G p.E660= | Silent (SNP) | VAF 51/57 reads (89%) | called by muse, mutect2, varscan2
- PTPRN2 | c.255G>A p.A85= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs367915752; called by muse, mutect2, varscan2
- RPL8 | c.255C>G p.G85= | Silent (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- SHC4 | c.1296G>A p.R432= | Silent (SNP) | VAF 95/177 reads (54%) | called by muse, mutect2, varscan2
- TEKT1 | c.945G>A p.T315= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs536852793, COSV100106020; called by muse, mutect2, varscan2
- XBP1 | c.75C>A p.A25= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9512G>A | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs782432978, COSV73145261; called by muse, mutect2
- ADAMTS9 | c.5719-98T>G | Intron (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- AL450336.1 | n.64T>A | RNA (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- AMD1 | c.*1902A>G | 3'UTR (SNP) | VAF 43/43 reads (100%) | catalogued as rs565494781; called by muse, mutect2, varscan2
- B3GNT6 | c.*540C>T | 3'UTR (SNP) | VAF 95/307 reads (31%) | catalogued as rs1404525902; called by muse, mutect2, varscan2
- BHLHE40-AS1 | n.966-83G>T | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- BMI1 | c.317-12A>G | Intron (SNP) | VAF 16/42 reads (38%) | catalogued as rs767233105; called by muse, mutect2, varscan2
- C2orf72 | c.*434A>G | 3'UTR (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- CADM2 | chr3:84959208 T>G | 5'Flank (SNP) | VAF 89/192 reads (46%) | called by muse, mutect2, varscan2
- CCDC14 | c.373+76A>G | Intron (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CDC6 | c.*314C>A | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- CDH2 | c.173-31565G>A | Intron (SNP) | VAF 99/215 reads (46%) | catalogued as rs1366216646; called by muse, mutect2, varscan2
- DDX19A | c.*376T>C | 3'UTR (SNP) | VAF 105/177 reads (59%) | called by muse, mutect2, varscan2
- DPH6 | c.312+17138G>C | Intron (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- DUSP7 | c.952+1197T>G | Intron (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- EPB41L4B | c.*261A>T | 3'UTR (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- FGD4 | c.600+322G>A | Intron (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- GPR55 | chr2:230908798 C>T | 3'Flank (SNP) | VAF 162/318 reads (51%) | called by muse, mutect2, varscan2
- IFI30 | c.637-106C>T | Intron (SNP) | VAF 30/90 reads (33%) | catalogued as rs1028604703; called by mutect2, varscan2
- IGHV3-21 | c.-34C>G | 5'UTR (SNP) | VAF 46/46 reads (100%) | catalogued as rs370198896; called by muse, varscan2
- IL13 | c.*636G>A | 3'UTR (SNP) | VAF 15/42 reads (36%) | catalogued as rs370110665; called by muse, mutect2, varscan2
- IQSEC1 | c.*1504A>C | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- IQSEC1 | c.*1418T>C | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as rs903459064; called by muse, mutect2, varscan2
- LONRF2 | c.*4702C>T | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- MAGEA3 | c.*25G>A | 3'UTR (SNP) | VAF 110/370 reads (30%) | called by muse, mutect2, varscan2
- MAP9 | c.*4618T>A | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- MATR3 | c.*2005dup | 3'UTR (INS) | VAF 34/100 reads (34%) | catalogued as rs1561950206; called by mutect2, pindel, varscan2
- MRPS14 | c.*543T>C | 3'UTR (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- NDUFV1 | c.156-29C>T | Intron (SNP) | VAF 182/627 reads (29%) | called by muse, mutect2, varscan2
- NIT1 | c.98+113A>C | Intron (SNP) | VAF 11/16 reads (69%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-8248C>A | Intron (SNP) | VAF 56/84 reads (67%) | called by muse, mutect2, varscan2
- PEF1 | c.*487C>G | 3'UTR (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- PIAS1 | c.*2961G>C | 3'UTR (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- PTPRD | c.*1219A>T | 3'UTR (SNP) | VAF 91/189 reads (48%) | called by muse, mutect2, varscan2
- PTPRT | c.*7721C>A | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- RGPD3 | chr2:106391186 G>A | 3'Flank (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- SETD5 | c.178-32del | Intron (DEL) | VAF 39/142 reads (27%) | called by mutect2, pindel, varscan2
- SLC1A3 | c.*1831A>G | 3'UTR (SNP) | VAF 57/85 reads (67%) | called by muse, mutect2, varscan2
- SPON2 | c.*481G>C | 3'UTR (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- SPTLC3 | c.-180A>C | 5'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- STPG2 | c.*733A>C | 3'UTR (SNP) | VAF 92/149 reads (62%) | called by muse, mutect2, varscan2
- SUB1 | c.*2022T>C | 3'UTR (SNP) | VAF 40/97 reads (41%) | catalogued as rs992370198; called by muse, mutect2, varscan2
- SYNPO2 | c.*2453T>C | 3'UTR (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- TBXA2R | c.*188C>T | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- TECRL | chr4:64277002 G>A | 3'Flank (SNP) | VAF 83/330 reads (25%) | called by muse, mutect2
- TLK2 | c.969-17G>A | Intron (SNP) | VAF 19/33 reads (58%) | catalogued as rs752341637; called by muse, mutect2, varscan2
- TMEM64 | c.*3548G>A | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2
- TMSB4X | c.-17+156C>T | Intron (SNP) | VAF 51/51 reads (100%) | catalogued as COSV104432406; called by muse, mutect2, varscan2
- UBBP4 | n.607C>A | RNA (SNP) | VAF 22/54 reads (41%) | called by muse, varscan2
- YDJC | c.325-35C>T | Intron (SNP) | VAF 12/163 reads (7%) | catalogued as rs747315532; called by muse, mutect2
- ZNF273 | c.*185C>T | 3'UTR (SNP) | VAF 21/68 reads (31%) | catalogued as rs1231327138; called by muse, mutect2, varscan2
